Surgical pathology report (de-identified scan), TCGA case TCGA-30-1856, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Harvard, specimen TCGA-30-1856-01A (Primary Tumor).

[page 1 of 3]
Accession Number: [REDACTED]

Report Status: Final

Type: Surgical Pathology

Pathology Report

SOFT TISSUE BIOPSY

Accessioned On: [REDACTED]

TCGA-30-1856

DIAGNOSIS:

SPECIMEN LABELED "TUMOR FROM RIGHT COLON" (including FSA):
METASTATIC PAPILLARY SEROUS ADENOCARCINOMA.

SPECIMEN LABELED "TUMOR FROM TRANSVERSE COLON":
METASTATIC PAPILLARY SEROUS ADENOCARCINOMA (largest metastatic focus 8.0 cm).

SPECIMEN LABELED "TUMOR FROM RIGHT COLON":
METASTATIC PAPILLARY SEROUS ADENOCARCINOMA (12.5 cm).

SPECIMEN LABELED "TUMOR FROM CECUM":
METASTATIC PAPILLARY SEROUS ADENOCARCINOMA,

SPECIMEN LABELED "TUMOR FROM MESENTERIC SMALL BOWEL":
METASTATIC PAPILLARY SEROUS ADENOCARCINOMA.

SPECIMEN LABELED "LEFT ADNEXA":
PAPILLARY SEROUS ADENOCARCINOMA (6.2cm), moderately to poorly differentiated, involving entire ovary and inked capsular surface.
Tumor involves mesosalpinx.
No residual ovarian tissue identified.
Adhesions.

SPECIMEN LABELED "RIGHT ADNEXA":
PAPILLARY SEROUS ADENOCARCINOMA (7.0 cm), moderately to poorly differentiated, involving ovary and extending to inked capsular surface.
Tumor involves mesosalpinx.
Lymphovascular invasion is identified.
Residual ovarian tissue is present.

SPECIMEN LABELED "UTERUS AND CERVIX":
METASTATIC PAPILLARY SEROUS ADENOCARCINOMA involving anterior and posterior serosal surfaces and pericervical soft tissue.
Squamous metaplasia of the cervix.
Atrophic endometrium.
Submucosal and intramural leiomyomata (largest 3.0 cm) with degenerative changes.

SPECIMEN LABELED "TUMOR FROM CUL-DE-SAC":
METASTATIC PAPILLARY SEROUS ADENOCARCINOMA.

SPECIMEN LABELED "TUMOR FROM BLADDER":
METASTATIC PAPILLARY SEROUS ADENOCARCINOMA.

CLINICAL DATA:

History: [REDACTED] with bilateral ovarian masses.

Operation: Laparotomy, TAH/BSO, cytoreductive surgery for ovarian cancer

Clinical Diagnosis: Ovarian masses

TISSUE SUBMITTED: 1. Tumor from right colon (FS)
2. Tumor from transverse colon
3. Tumor from right colon
4. Tumor from cecum
5. Tumor from mesenteric small bowel
6. Left adnexa
7. Right adnexa
8. Uterus with cervix
9. Tumor from cul de sac
10. Tumor from bladder

[page 2 of 3]
O.R. CONSULTATION: #
SPECIMEN LABELED "#1 TUMOR FROM RIGHT COLON" (FSA):
Papillary serous adenocarcinoma.

GROSS DESCRIPTION:

The specimen is received fresh, in 10 parts, each labeled with the patient's name and unit number.

TCGA-30-1856

Part 1, "tumor from right colon", consists of one fragment of tan/red soft tissue (6.0 x 3.0 x 0.4 cm) with multiple tan/white firm, ill-defined nodules (0.8 cm in greatest dimension). A representative section is evaluated intraoperatively and submitted as "FSA". Additional representative sections are submitted.

Micro 1 - FSA remnant, 2 f,
Micro 2 - additional sections of nodules, 5 f,

Part 2, "tumor from transverse colon", consists of a single fragment of fibroadipose tissue consistent with omentum (23 x 9 x 3.5 cm). At one aspect of the specimen, there are multiple nodules of tan/white, firm tumor (8.0 cm greatest dimension). At least five possible nodules are identified, the largest greatest dimension having an area of central necrosis. Representative sections are submitted.

Micro 3 - largest nodule, 1 f,
Micro 4 - additional nodules, 3 f,

Part 3, "tumor from right colon", consists of a single fragment of pink/yellow fibroadipose tissue (12.5 x 9 x 3.5 cm) which is almost entirely infiltrated with an ill-defined, firm, tan/white tumor mass. Areas of possible necrosis are identified. Representative sections are submitted.

Micro 5 - solid tumor nodule, 1 f,
Micro 6 - additional tumor, 1 f,

Part 4, "tumor from cecum", consists of multiple fragments (about 8 to 10) of tan/grey, focally firm tissue (2.5 x 1.8 x 0.6 cm in aggregate). A small amount of yellow adipose tissue is also present. The specimen is entirely submitted.

Micro 7 - tumor from cecum, multiple frags

Part 5, "tumor from mesenteric small bowel", consists of multiple fragments (approximately 10) of tan/grey firm tissue and yellow adipose tissue (4 x 2.5 x 0.7 cm in aggregate). Representative sections are submitted.

Micro 8 - tumor from mesenteric small bowel, 6 f,

Part 6, "left adnexa", consists of a firm nodular mass (6.2 x 5.0 x 2.7 cm), and attached fallopian tube (4.5 cm in length by 0.8 cm in maximum diameter). The outer surface of the mass is tan/grey, friable with papillary excrescences consistent with surface involvement by tumor. Sectioning reveals the mass to consist of solid, tan/white, centrally necrotic granular tissue with no residual ovarian tissue identified. The mass abutts and may invade the adjacent adherent fallopian tube, at its proximal aspect. The fallopian tube is fimbriated but otherwise unremarkable. Representative sections are submitted.

Micro 9 - fallopian tube & adjacent tumor, 3 f,
Micro 10-12 - tumor mass & adjacent fallopian tube, 4 f,

Part 7, "right adnexa", consists of a tan/grey, firm nodular mass (7.0 x 4.5 x 3.5 cm) and attached fallopian tube (6.0 cm in length by 0.8 cm in maximum diameter). The surface of the mass is smooth and glistening, with focal areas of disruption and associated nodularity. Sectioning reveals the mass to consist of a solid, tan/white, firm tumor with areas of central necrosis, hemorrhage and softening. Residual ovarian tissue is identified at the

[page 3 of 3]
periphery. The tumor abutts the adjacent firmly adhered fallopian tube, and possibly invades it at its proximal extent. The tube is fimbriated and there are small tumor nodules (1.0 cm greatest dimension) adherent to the fimbria. Representative sections are submitted.

Micro 13 - fallopian tube & adjacent tumor, 3 f,
Micro 14-16 - adnexal mass, 6 f,

TCGA-30-1856

Part 8, "uterus and cervix", is an 89g hysterectomy specimen (8.5 x 5.5 x 4 cm in overall dimensions). The serosal surface is tan/pink and is covered with a tan/white nodular mass (5.5 x 5 x 0.4 cm) on the posterior aspect and several smaller nodules (up to 1.2 cm in greatest dimension) on the anterior surface. Similar appearing nodules are also present in the left paracervical tissue (4.5 x 1.5 x 0.4 cm). The exocervix (3.0 cm in diameter) is tan/pink, smooth and glistening and focally hemorrhagic, with an attached cuff of vaginal mucosa (0.3 to 0.8 cm in greatest extent) around the periphery. The endocervix (2.5 cm in length by 1.6 cm in greatest width) is tan/pink, smooth and glistening with a herringbone-like mucosal surface. The endometrium (4.0 cm from cornu to cornu by 4.2 cm in length by 0.2 cm in thickness) is tan, smooth and glistening and adhered in the vicinity of a submucosal leiomyoma (3.0 cm diameter) present in the anterior vaginal wall. This leiomyoma has a tan/white swirled appearance on cut section. The myometrium (1.4 cm in maximum thickness) contains additional leiomyomata, including a focally calcified leiomyoma (1.6 cm in maximum dimension) located superiorly in the fundus. Representative sections are submitted.

Micro 17 - anterior cervix & vaginal mucosa, 1 f,
Micro 18 - left lateral cervix (?pericervical tumor involvement), 1 f,
Micro 19 - posterior cervix & vaginal mucosa, 1 f,
Micro 20 - posterior LUS, 1 f,
Micro 21 - anterior endometrium & submucosal leio, 1 f,
Micro 22 - anterior serosa with nodularity, 1 f,
Micro 23 - superior leio & superior serosa, 1 f,
Micro 24 - posterior endomyometrium & serosa with nodule, 1 f,

Part 9, "tumor from cul de sac", consists of multiple fragments of tan/pink, focally hemorrhagic fibrous tissue (7 x 4.5 x 1.5 cm in aggregate). Some of the fragments are almost entirely composed of firm, tan/grey nodules, consistent with tumor. Representative sections are submitted.

Micro 25-26 - tumor from cul de sac, 5 frags,

Part 10, "tumor from bladder", consists of three fragments of membranous tan/pink, focally hemorrhagic soft tissue (11 x 3 x 0.5 cm, 3 x 0.8 x 0.7 cm and 2.5 x 0.9 x 0.7 cm) which exhibit a fine, tan/white nodularity on one surface. Representative sections are submitted.

Micro 27 - tumor from bladder, 3 frags,
Reports to:

SPECIMEN TYPE: SOFT TISSUE BIOPSY

ADDITIONAL SPECIMEN TYPE: SOFT TISSUE MASS OR SIMPLE EXCISION

ADDITIONAL SPECIMEN TYPE: SOFT TISSUE MASS OR SIMPLE EXCISION

ADDITIONAL SPECIMEN TYPE: SOFT TISSUE BIOPSY

ADDITIONAL SPECIMEN TYPE: SOFT TISSUE BIOPSY

ADDITIONAL SPECIMEN TYPE: UTERUS W/ OR W/O ADNEXA- OTH THAN NEPLAST OR PROL

ADDITIONAL SPECIMEN TYPE: SOFT TISSUE BIOPSY

ADDITIONAL SPECIMEN TYPE: URINARY BLADDER BIOPSY

Source: NCI Genomic Data Commons file 5a79fadf-f219-4e53-84af-5199a7f1290b (TCGA-30-1856.281005D7-4231-467C-9C6C-43F536FCEBE1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).